Somatic mutation profile of tumor specimen TCGA-BT-A20X-01A (aliquot TCGA-BT-A20X-01A-11D-A16O-08) from TCGA case TCGA-BT-A20X, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Dome of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 56.2 years (20,519 days).
Specimen TCGA-BT-A20X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6d2efb5-3305-40f8-a79a-9db9bc6c306c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BT-A20X-11A (Solid Tissue Normal), aliquot TCGA-BT-A20X-11A-12D-A16O-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d29737aa-5cb9-4660-8169-e699e958ebc1

The open-access MAF lists 74 somatic variants for this specimen: 56 protein-altering or splice-affecting, 15 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 15, Nonsense Mutation 5, 5'Flank 2, Splice Site 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTL7B | c.857G>T p.G286V | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65927215; called by muse, mutect2, varscan2
- AFF3 | c.1957C>T p.R653W | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1451684970, COSV57850269; called by muse, mutect2, varscan2
- AK8 | c.1313G>A p.R438K | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.237); catalogued as rs1487711415, COSV53752996; called by muse, mutect2, varscan2
- ANKRD42 | c.310C>T p.L104F | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV52615410; called by muse, mutect2, varscan2
- C7 | c.379T>G p.S127A | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV57473248; called by muse, mutect2, varscan2
- CARD11 | c.944A>G p.D315G | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as COSV67798370; called by muse, mutect2, varscan2
- CD101 | c.129C>A p.C43* | Nonsense Mutation (SNP) | VAF 22/85 reads (26%) | catalogued as COSV99870268; called by muse, mutect2, varscan2
- CDH2 | c.1070A>G p.N357S | Missense Mutation (SNP) | VAF 32/201 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as rs1209862742, COSV52277464; called by muse, mutect2, varscan2
- CHD6 | c.7010C>T p.S2337L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as rs904014749, COSV100951409; called by muse, mutect2
- CNTLN | c.2548A>G p.I850V | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as COSV52074489; called by muse, mutect2, varscan2
- CSMD3 | c.11051C>A p.T3684N (on ENST00000297405 / NM_001363185.1; = p.T3515N on NM_052900.3) | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV52153093; called by muse, mutect2, varscan2
- CYP2C18 | c.980T>C p.I327T | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758639306, COSV53671384; called by muse, mutect2, varscan2
- DIXDC1 | c.466G>T p.A156S | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV59461631; called by muse, mutect2, varscan2
- EGLN2 | c.535C>G p.L179V | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1052892437, COSV58279684; called by muse, mutect2, varscan2
- EIF4G3 | c.3484G>T p.D1162Y | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51679703; called by muse, mutect2, varscan2
- EP300 | c.6754G>T p.E2252* | Nonsense Mutation (SNP) | VAF 36/75 reads (48%) | catalogued as COSV54330500; called by muse, mutect2, varscan2
- FBN3 | c.8185G>T p.A2729S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.955); catalogued as rs780445413, COSV53664090; called by muse, varscan2
- GIMAP1 | c.859C>G p.L287V | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as COSV56187801; called by muse, mutect2, varscan2
- HEATR4 | c.633C>G p.N211K | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.47); catalogued as COSV58571452; called by muse, mutect2, varscan2
- HERC2 | c.2795A>T p.D932V | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.329); catalogued as COSV55318305; called by muse, mutect2, varscan2
- HOXA7 | c.172A>T p.N58Y | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); catalogued as COSV54217276; called by muse, mutect2, varscan2
- IKZF2 | c.1489G>A p.D497N | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV59577753; called by muse, varscan2
- IKZF2 | c.1420G>C p.E474Q | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV59577758; called by muse, varscan2
- IKZF2 | c.1287G>C p.K429N | Missense Mutation (SNP) | VAF 35/228 reads (15%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.717); catalogued as COSV59577761, COSV59584371; called by muse, mutect2, varscan2
- KMT2C | c.2698G>T p.G900* | Nonsense Mutation (SNP) | VAF 14/80 reads (18%) | catalogued as COSV100078449; called by muse, varscan2
- KMT2D | c.8229G>T p.Q2743H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56428741; called by muse, mutect2, varscan2
- KPNA1 | c.213G>C p.Q71H | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV60268490; called by muse, mutect2, varscan2
- KRTAP24-1 | c.183C>G p.C61W | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV104414029, COSV61089284, COSV61089856; called by muse, mutect2, varscan2
- LNPEP | c.1742A>G p.Y581C | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs200018527, COSV51477395; called by muse, mutect2, varscan2
- LRRC7 | c.1177A>G p.N393D (on ENST00000651989 / NM_001370785.2; = p.N360D on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50439812; called by muse, mutect2, varscan2
- LRRIQ1 | c.3671A>G p.K1224R | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV67825759, COSV67827919; called by muse, mutect2, varscan2
- MAT1A | c.1160G>C p.W387S | Missense Mutation (SNP) | VAF 62/216 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64745234; called by muse, mutect2, varscan2
- MGAT1 | c.424G>T p.D142Y | Missense Mutation (SNP) | VAF 18/51 reads (35%) | PolyPhen probably damaging (0.997); catalogued as COSV57133821; called by muse, mutect2, varscan2
- MGAT1 | c.423G>T p.Q141H | Missense Mutation (SNP) | VAF 18/50 reads (36%) | PolyPhen possibly damaging (0.621); catalogued as COSV57133827; called by muse, mutect2, varscan2
- MTBP | c.1300C>A p.H434N | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.018); catalogued as COSV59962174; called by muse, mutect2, varscan2
- PCDHGA2 | c.2044G>A p.A682T | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.006); catalogued as rs769248665, COSV53929048; called by muse, mutect2, varscan2
- PIWIL3 | c.1805G>T p.C602F | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.118); catalogued as COSV59994790; called by muse, mutect2
- PON3 | c.715G>T p.V239L | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV55698895; called by muse, mutect2, varscan2
- RANBP10 | c.1057T>A p.S353T | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.158); catalogued as COSV58157105; called by muse, mutect2, varscan2
- RASGEF1A | c.706G>C p.E236Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.211); catalogued as COSV100988745; called by muse, mutect2
- RNF10 | c.1448G>T p.C483F | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as COSV58044527; called by muse, mutect2, varscan2
- SELENBP1 | c.1407C>A p.D469E | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV64373281; called by muse, mutect2, varscan2
- SIT1 | c.80G>T p.C27F | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.05); catalogued as COSV52399782; called by muse, mutect2, varscan2
- SNX33 | c.1598A>G p.H533R | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV57913248; called by muse, mutect2, varscan2
- STAG1 | c.1574T>G p.L525R | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV52606915; called by muse, mutect2, varscan2
- SYTL4 | c.1651G>C p.V551L | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV52167035; called by muse, mutect2, varscan2
- TDO2 | c.880A>C p.M294L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as COSV72542726; called by muse, mutect2, varscan2
- TMEM200A | c.906G>T p.E302D | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.381); catalogued as COSV51651785; called by muse, mutect2, varscan2
- TP53 | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 16/46 reads (35%) | catalogued as COSV52679869, COSV53267121, COSV53424574; called by muse, mutect2, varscan2
- TUT7 | c.1052C>A p.S351* | Nonsense Mutation (SNP) | VAF 34/116 reads (29%) | catalogued as COSV52896886, COSV99463897; called by muse, mutect2, varscan2
- TYW1 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.014); catalogued as COSV55887359; called by muse, mutect2, varscan2
- USH1G | c.515G>C p.R172P | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.109); catalogued as COSV58881474; called by muse, mutect2, varscan2
- ZBED9 | c.3457G>T p.D1153Y | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.993); catalogued as COSV71729302; called by muse, mutect2, varscan2
- ZNF831 | c.4231C>T p.H1411Y | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as COSV64037722, COSV64039146; called by muse, mutect2, varscan2
- BRINP1 | c.1146-1G>A p.X382_splice | Splice Site (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
- CDH11 | c.1096del p.D366Tfs*3 | Frame Shift Del (DEL) | VAF 36/141 reads (26%) | called by mutect2, pindel, varscan2
- AMDHD2 | c.201C>T p.F67= | Silent (SNP) | VAF 27/97 reads (28%) | catalogued as rs367882539; called by muse, mutect2, varscan2
- APLP2 | c.1803C>T p.P601= | Silent (SNP) | VAF 29/95 reads (31%) | catalogued as COSV53840275; called by muse, mutect2, varscan2
- BOD1L1 | c.6456C>T p.F2152= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as rs139854434, COSV50007842; called by muse, mutect2, varscan2
- CYP2B6 | c.1170C>G p.L390= | Silent (SNP) | VAF 52/161 reads (32%) | catalogued as COSV57843290; called by muse, mutect2, varscan2
- FKBP9 | c.921G>A p.T307= | Silent (SNP) | VAF 42/134 reads (31%) | catalogued as rs138779515; called by muse, mutect2, varscan2
- FRY | c.3042A>G p.E1014= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as COSV66568401; called by muse, mutect2, varscan2
- IKZF2 | c.1008G>C p.L336= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as COSV100563839, COSV59577772; called by muse, mutect2, varscan2
- KIAA0100 | c.537A>G p.L179= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs376138048, COSV66491984; called by muse, mutect2, varscan2
- MUC16 | c.21951C>T p.I7317= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as rs745945024, COSV67459201; called by muse, mutect2, varscan2
- OR10K2 | c.72G>A p.Q24= | Silent (SNP) | VAF 30/97 reads (31%) | catalogued as COSV59220955; called by muse, mutect2, varscan2
- OR8I2 | c.762G>A p.L254= | Silent (SNP) | VAF 24/150 reads (16%) | catalogued as rs866731048, COSV56167475; called by muse, mutect2, varscan2
- PDZD2 | c.1642C>T p.L548= | Silent (SNP) | VAF 14/106 reads (13%) | catalogued as COSV56855986; called by muse, mutect2, varscan2
- PKHD1 | c.1495A>C p.R499= | Silent (SNP) | VAF 15/108 reads (14%) | catalogued as COSV61870191; called by muse, mutect2, varscan2
- TUT7 | c.1419G>A p.R473= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV52895142; called by muse, mutect2, varscan2
- ZBTB46 | c.438C>T p.I146= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs142438754; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498799 G>T | 5'Flank (SNP) | VAF 23/182 reads (13%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498800 T>A | 5'Flank (SNP) | VAF 22/180 reads (12%) | called by muse, mutect2, varscan2
- CXCL12 | c.266+836T>C | Intron (SNP) | VAF 8/24 reads (33%) | catalogued as COSV59107556; called by muse, mutect2, varscan2
